Somatic mutation profile of tumor specimen MMRF_1939_1_BM_CD138pos (aliquot MMRF_1939_1_BM_CD138pos_T1_KHS5U_L08852) from MMRF case MMRF_1939, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.3 years (24,959 days).
Specimen MMRF_1939_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d2383b4-8461-478b-8319-ce199628c634.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1939_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1939_1_PB_Whole_C2_KHS5U_L08765; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89ab156c-c04d-4512-bf45-d595891d50ed

The open-access MAF lists 106 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 31, Intron 13, Silent 9, 5'UTR 6, 3'Flank 4, Splice Site 3, RNA 2, Nonsense Mutation 1, Splice Region 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 32/327 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2
- AOAH | c.626G>A p.S209N | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1247831875; called by muse, mutect2, varscan2
- AUTS2 | c.626G>A p.S209N | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as rs373179538; called by muse, mutect2, varscan2
- C2orf81 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs746985748; called by muse, mutect2, varscan2
- IGKV4-1 | c.184T>A p.Y62N | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs183392966; called by muse, mutect2, varscan2
- MYO9B | c.5534C>A p.A1845E | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68277838; called by muse, mutect2, varscan2
- MYOM2 | c.2426C>T p.T809I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1221779722, COSV50703911; called by muse, mutect2
- PCLO | c.15327G>T p.K5109N | Missense Mutation (SNP) | VAF 92/438 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100428224; called by muse, mutect2, varscan2
- PERM1 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as rs545665777; called by muse, mutect2, varscan2
- PLEKHN1 | c.1364G>A p.R455H (on ENST00000379409; = p.R403H on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs571820575, COSV58023218; called by muse, mutect2, varscan2
- SSTR1 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99942967; called by muse, mutect2, varscan2
- TRIOBP | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 32/662 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs746465206, COSV60375256; called by muse, mutect2
- ZNF638 | c.122G>T p.R41I | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV104389371; called by muse, mutect2
- CACNA1E | c.6574G>T p.G2192C (on ENST00000367573 / NM_001205293.3; = p.G2149C on NM_000721.4) | Missense Mutation (SNP) | VAF 37/323 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- CAMK2G | c.1023+1G>T p.X341_splice (on ENST00000423381 / NM_001367518.1; = p.X362_splice on NM_172169.3 and 8 other RefSeq transcripts) | Splice Site (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- CCDC157 | c.775C>A p.Q259K | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC74B | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CILP | c.2790C>G p.N930K | Missense Mutation (SNP) | VAF 57/299 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- COP1 | c.1424G>A p.C475Y | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CRISP3 | c.326A>G p.N109S (on ENST00000371159 / NM_001368123.1; = p.N91S on NM_006061.4) | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- IGLV3-27 | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- IMP4 | c.594+7C>G | Splice Region (SNP) | VAF 28/296 reads (9%) | called by muse, mutect2
- LETMD1 | c.996T>G p.I332M | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- MLLT6 | c.1228T>C p.S410P | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- MUC22 | c.772A>G p.T258A | Missense Mutation (SNP) | VAF 133/738 reads (18%) | SIFT tolerated, low confidence (0.23); called by muse, mutect2, varscan2
- NLGN4X | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NSMAF | c.929T>G p.L310R | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- OSBPL1A | c.520C>G p.Q174E | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- OSBPL1A | c.519T>A p.D173E | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPIP5K1 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 56/490 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- PRICKLE2 | c.349G>T p.V117F (on ENST00000295902; = p.V61F on NM_198859.4) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- STK10 | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STXBP4 | c.1355G>A p.S452N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TBC1D23 | c.772+2T>A p.X258_splice | Splice Site (SNP) | VAF 5/16 reads (31%) | called by muse, varscan2
- TNFSF11 | c.893T>C p.L298S | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIM64C | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.323); called by muse, mutect2
- UTP4 | c.1164+1G>A p.X388_splice | Splice Site (SNP) | VAF 17/177 reads (10%) | called by muse, mutect2, varscan2
- ZNF292 | c.5866_5890del p.K1956Sfs*17 | Frame Shift Del (DEL) | VAF 9/103 reads (9%) | called by mutect2, pindel
- ZNF608 | c.2651A>G p.D884G | Missense Mutation (SNP) | VAF 47/256 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF675 | c.1492C>G p.H498D | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC053503.6 | c.669G>A p.E223= | Silent (SNP) | VAF 25/194 reads (13%) | called by muse, mutect2, varscan2
- ADARB2 | c.999G>A p.Q333= | Silent (SNP) | VAF 21/178 reads (12%) | catalogued as rs558158478; called by muse, mutect2, varscan2
- ADGRE3 | c.57T>G p.A19= | Silent (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2, varscan2
- FGA | c.2553T>C p.Y851= | Silent (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- MTG2 | c.1179G>A p.A393= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs767461500, COSV63694953; called by muse, mutect2, varscan2
- OR8B12 | c.354G>A p.A118= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as rs764768343, COSV60911867; called by muse, mutect2, varscan2
- SLC6A17 | c.378C>T p.R126= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs764725330, COSV58995788; called by muse, mutect2, varscan2
- SVIL | c.6408G>A p.T2136= (on ENST00000355867 / NM_021738.3; = p.T1710= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/181 reads (20%) | catalogued as rs1383455684, COSV63442631; called by muse, mutect2, varscan2
- TOP3A | c.1050T>C p.I350= | Silent (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- AC093802.1 | n.1914+9412A>T | Intron (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- ACTR2 | c.*1723C>A | 3'UTR (SNP) | VAF 53/439 reads (12%) | catalogued as rs1326407366; called by muse, mutect2, varscan2
- AGTR2 | c.*250_*261del | 3'UTR (DEL) | VAF 21/97 reads (22%) | called by mutect2, pindel, varscan2
- AL049777.1 | n.510+4458A>G | Intron (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- AL096814.1 | c.*24del | 3'UTR (DEL) | VAF 33/228 reads (14%) | catalogued as COSV50004302; called by mutect2, pindel, varscan2
- ALDH9A1 | c.*557del | 3'UTR (DEL) | VAF 33/85 reads (39%) | called by mutect2, pindel, varscan2
- ARHGAP20 | c.105+226A>G | Intron (SNP) | VAF 17/118 reads (14%) | called by muse, mutect2, varscan2
- ATP1A3 | c.*196C>T | 3'UTR (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- BCAT1 | c.*3260A>G | 3'UTR (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021030 T>C | 5'Flank (SNP) | VAF 33/187 reads (18%) | catalogued as rs1340417121; called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+39710G>T | Intron (SNP) | VAF 29/189 reads (15%) | called by muse, mutect2, varscan2
- BPNT2 | c.*2937A>C | 3'UTR (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- CELA3A | c.362+125G>A | Intron (SNP) | VAF 22/233 reads (9%) | called by muse, mutect2
- CRAT | c.291+76C>T | Intron (SNP) | VAF 50/329 reads (15%) | catalogued as rs200106516; called by muse, mutect2, varscan2
- CSRNP3 | c.*3469T>G | 3'UTR (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2, varscan2
- CTNND1 | c.*47dup | 3'UTR (INS) | VAF 17/98 reads (17%) | called by mutect2, pindel, varscan2
- DAAM2 | c.*1464C>A | 3'UTR (SNP) | VAF 17/103 reads (17%) | called by muse, mutect2, varscan2
- DRAXIN | c.*2697C>T | 3'UTR (SNP) | VAF 46/160 reads (29%) | called by muse, mutect2, varscan2
- FAM8A1 | c.*375G>A | 3'UTR (SNP) | VAF 6/18 reads (33%) | catalogued as rs200864954; called by muse, mutect2, varscan2
- GPR83 | c.*1597C>A | 3'UTR (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- GRM7 | c.-196C>T | 5'UTR (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- HECA | c.-101G>C | 5'UTR (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2
- HMG20B | c.*105C>T | 3'UTR (SNP) | VAF 76/417 reads (18%) | catalogued as rs769067411; called by muse, mutect2, varscan2
- HMGA2 | c.*427A>G | 3'UTR (SNP) | VAF 24/124 reads (19%) | called by muse, mutect2, varscan2
- HNRNPF | chr10:43385696 C>A | 3'Flank (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- IGFBP5 | c.*2778G>A | 3'UTR (SNP) | VAF 21/159 reads (13%) | catalogued as rs1199252254; called by muse, mutect2, varscan2
- KIAA1143 | c.*1551A>G | 3'UTR (SNP) | VAF 173/942 reads (18%) | called by muse, varscan2
- KIAA1217 | c.*1086T>A | 3'UTR (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- KIAA1549 | c.*970A>G | 3'UTR (SNP) | VAF 5/120 reads (4%) | called by muse, mutect2
- LRRN4CL | c.*7C>A | 3'UTR (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- MAGEF1 | c.*234G>A | 3'UTR (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2, varscan2
- MLLT6 | c.819+303G>C | Intron (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2, varscan2
- MRNIP | c.-8_-2del | 5'UTR (DEL) | VAF 42/228 reads (18%) | called by mutect2, pindel, varscan2
- MVB12A | c.413+75G>A | Intron (SNP) | VAF 36/192 reads (19%) | called by muse, mutect2, varscan2
- MYH15 | c.-8A>G | 5'UTR (SNP) | VAF 29/257 reads (11%) | called by muse, mutect2, varscan2
- MZT1 | c.*1191C>T | 3'UTR (SNP) | VAF 13/134 reads (10%) | called by muse, mutect2
- NAMPTP1 | n.1983C>A | RNA (SNP) | VAF 46/458 reads (10%) | called by muse, mutect2, varscan2
- NCAM2 | c.*968T>G | 3'UTR (SNP) | VAF 21/109 reads (19%) | called by muse, mutect2, varscan2
- NEK10 | chr3:27110554 A>T | 3'Flank (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2, varscan2
- PAFAH1B2 | c.*2663G>A | 3'UTR (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- PI15 | c.*1997A>T | 3'UTR (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- PKN2 | c.-205T>A | 5'UTR (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- RAP1GAP | c.1429-844T>C | Intron (SNP) | VAF 24/189 reads (13%) | called by muse, mutect2, varscan2
- ROPN1 | c.116+85C>A | Intron (SNP) | VAF 64/730 reads (9%) | called by muse, mutect2
- RRN3P1 | n.2547A>T | RNA (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- S1PR3 | c.*166G>A | 3'UTR (SNP) | VAF 21/243 reads (9%) | catalogued as rs535648295; called by muse, mutect2
- SLC24A5 | c.301+2091A>G | Intron (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- SMAD9 | c.*3179G>T | 3'UTR (SNP) | VAF 12/82 reads (15%) | called by mutect2, varscan2
- TCF7L2 | c.553-11310A>G | Intron (SNP) | VAF 32/183 reads (17%) | called by muse, mutect2, varscan2
- TFCP2L1 | c.*6199T>C | 3'UTR (SNP) | VAF 20/111 reads (18%) | called by muse, mutect2, varscan2
- TGFBRAP1 | chr2:105264671 G>T | 3'Flank (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- TMEM135 | c.*1713C>T | 3'UTR (SNP) | VAF 10/85 reads (12%) | catalogued as rs1005576805; called by muse, mutect2, varscan2
- TMEM138 | c.129-294A>G | Intron (SNP) | VAF 4/81 reads (5%) | called by muse, mutect2
- TNRC6C | c.*3468T>C | 3'UTR (SNP) | VAF 28/155 reads (18%) | called by muse, mutect2, varscan2
- TRIM71 | c.*137A>T | 3'UTR (SNP) | VAF 6/78 reads (8%) | catalogued as rs1239818666, COSV67470745; called by muse, mutect2
- VEGFA | chr6:43785223 G>C | 3'Flank (SNP) | VAF 18/120 reads (15%) | called by muse, mutect2, varscan2
- ZNF711 | c.-158G>T | 5'UTR (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
